Somatic mutation profile of tumor specimen TCGA-QR-A70H-01A (aliquot TCGA-QR-A70H-01A-12D-A35D-08) from TCGA case TCGA-QR-A70H, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 36.5 years (13,314 days).
Specimen TCGA-QR-A70H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc000156-4d87-4974-890e-d921ae7d3542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70H-10A (Blood Derived Normal), aliquot TCGA-QR-A70H-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1087dda0-5db6-4fbf-a32f-d4898a3c3a72

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPUL2 | c.1532del p.L511* | Frame Shift Del (DEL) | VAF 67/220 reads (30%) | catalogued as rs1263686326; called by mutect2, pindel, varscan2
- MLLT6 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs981395300; called by muse, mutect2, varscan2
- PRUNE2 | c.5125G>A p.V1709I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs762338253, COSV100944204; called by muse, mutect2, varscan2
- ADGRA2 | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRCA2 | c.9289T>C p.C3097R | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- GLG1 | c.2330T>G p.V777G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- IHH | c.279C>G p.D93E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- MTFR1 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- NUDCD2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF77 | c.255A>C p.E85D | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ETV7 | c.222C>T p.C74= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs1384776075; called by muse, mutect2, varscan2
- NUDCD2 | c.117C>A p.R39= | Silent (SNP) | VAF 61/151 reads (40%) | called by muse, mutect2, varscan2
